Somatic mutation profile of tumor specimen TARGET-20-PARUNX-04A (aliquot TARGET-20-PARUNX-04A-01D) from TARGET case TARGET-20-PARUNX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,321 days).
Specimen TARGET-20-PARUNX-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e90f9796-fee2-4f09-85e7-b8b00c8c1d19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUNX-14A (Bone Marrow Normal), aliquot TARGET-20-PARUNX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f478ca50-d366-4e74-97f4-acc241bc4b15

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 112/375 reads (30%) | catalogued as COSV64875973; called by muse, mutect2, varscan2
- CCDC114 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.287); catalogued as rs1186646725; called by muse, mutect2, varscan2
- COL6A1 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV62612919; called by muse, mutect2, varscan2
- MAGEA10 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV54885843, COSV54886058; called by muse, mutect2, varscan2
- MUC16 | c.27512C>T p.S9171L | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs375432429; called by muse, mutect2, varscan2
- MYO6 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs551471138, COSV64121378; called by muse, varscan2
- POF1B | c.1452G>C p.Q484H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53140426; called by muse, mutect2, varscan2
- ITGA2 | c.1816G>C p.G606R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2
- WDFY3 | c.1024del p.L342* | Frame Shift Del (DEL) | VAF 59/192 reads (31%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3459C>T p.D1153= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1427946992, COSV66215045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG9 | c.525C>T p.D175= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as rs150952802, COSV52484598; called by muse, mutect2, varscan2
- TECTB | c.*21G>A | 3'UTR (SNP) | VAF 56/128 reads (44%) | catalogued as rs373188262; called by muse, mutect2
